FM case AD10984 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon.
https://portal.gdc.cancer.gov/cases/4fb885d6-ab54-4241-8bcb-e989a478504a

Female, 71.4 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the colon; primary biopsied or resected from the colon. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
